Somatic mutation profile of tumor specimen TCGA-AX-A2IN-01A (aliquot TCGA-AX-A2IN-01A-12D-A17W-09) from TCGA case TCGA-AX-A2IN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 63.7 years (23,275 days).
Specimen TCGA-AX-A2IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dd00d2c-00ac-4d90-9f66-ec05e8a27cd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2IN-10A (Blood Derived Normal), aliquot TCGA-AX-A2IN-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d9c01a9-dc36-41dc-abab-a9cd11ad88bf

The open-access MAF lists 645 somatic variants for this specimen: 472 protein-altering or splice-affecting, 157 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 157, Frame Shift Del 93, Frame Shift Ins 23, Nonsense Mutation 17, Splice Site 9, Splice Region 5, Intron 5, RNA 3, 5'UTR 3, In Frame Del 3, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MAN2B1 | c.2402del p.G801Afs*4 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs797044680, CM051105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NR2E3 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489149705, CM000533, COSV100489463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1057519938, COSV55881772, COSV55902438, COSV55902706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554898067, CM1111457, COSV64291669, COSV64295080, COSV64295612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RB1 | c.1128-2A>G p.X376_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as rs1131690892, CS145469, COSV57306578, COSV57311966; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1959dup p.V654Sfs*14 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | catalogued as rs1566234123; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99593344; called by muse, mutect2, varscan2
- ABCA4 | c.6808C>T p.Q2270* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100933149; called by muse, mutect2, varscan2
- ABCC2 | c.890del p.K297Rfs*14 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as rs759781877; called by mutect2, varscan2
- ABRAXAS2 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886267709, COSV100044988; called by muse, mutect2, varscan2
- AC011462.1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs535975575, COSV54195841; called by muse, mutect2, varscan2
- ACSM1 | c.1732T>C p.*578Qext*31 | Nonstop Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV99533081; called by muse, mutect2, varscan2
- ACTN2 | c.2366T>C p.L789P | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV100856856; called by muse, mutect2, varscan2
- ADA2 | c.926T>C p.M309T (on ENST00000262607; = p.M68T on NM_177405.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs1484632427, COSV99376137; called by muse, mutect2, varscan2
- ADAMTS20 | c.221T>C p.M74T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101239491; called by muse, mutect2, varscan2
- ADH7 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV99265308; called by muse, mutect2, varscan2
- AHNAK | c.5482G>A p.D1828N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as rs374000220; called by muse, mutect2, varscan2
- AJAP1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV65454410; called by muse, mutect2, varscan2
- AL592490.1 | c.1658T>C p.F553S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.954); catalogued as COSV101308219; called by muse, mutect2
- ALDH1B1 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs147930374, COSV66619331; called by muse, mutect2, varscan2
- ALG1L | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1441258728, COSV100444823; called by muse, mutect2, varscan2
- ALOX12B | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047233; called by muse, mutect2, varscan2
- ANKRD11 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV99969703; called by muse, mutect2, varscan2
- APAF1 | c.3475G>A p.G1159S (on ENST00000551964 / NM_181861.2; = p.G1105S on NM_001160.3) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs778943117, COSV100244149; called by muse, mutect2, varscan2
- ARHGAP21 | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100256342; called by muse, mutect2, varscan2
- ARHGEF17 | c.1678C>A p.R560S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.048); catalogued as COSV55232132; called by muse, mutect2, varscan2
- ARHGEF18 | c.2092C>T p.R698* (on ENST00000359920 / NM_001130955.2; = p.R594* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as rs750656837, COSV60467761; called by muse, mutect2, varscan2
- ARID1A | c.6521T>G p.L2174R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100252059; called by muse, mutect2, varscan2
- ARL14 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100296492; called by muse, mutect2, varscan2
- ARMCX1 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV100863199; called by muse, mutect2, varscan2
- ART1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374138196, COSV99167202; called by muse, mutect2, varscan2
- ATP2B3 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV99684791; called by muse, mutect2, varscan2
- ATP6V1H | c.677+2T>C p.X226_splice | Splice Site (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100778665; called by muse, mutect2, varscan2
- BACH2 | c.1969C>A p.R657S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57590379, COSV99999884; called by muse, mutect2, varscan2
- BCAR1 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1053124126, COSV99366812; called by muse, mutect2, varscan2
- BCKDK | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); catalogued as COSV54892749; called by muse, mutect2
- BCL9L | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100599943; called by muse, mutect2, varscan2
- BOP1 | c.106dup p.L36Pfs*34 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | catalogued as rs782133829; called by mutect2, varscan2
- BRWD1 | c.3737T>A p.I1246N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100313567; called by muse, mutect2, varscan2
- BTBD1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99915537; called by muse, mutect2, varscan2
- C3 | c.596T>A p.V199D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99836798; called by muse, mutect2, varscan2
- C3orf18 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs1226133334, COSV100597142; called by muse, mutect2, varscan2
- C3orf56 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1488329115, COSV101228964; called by muse, mutect2, varscan2
- C6orf136 | c.914C>T p.P305L (on ENST00000376473 / NM_001109938.3; = p.P171L on NM_145029.4) | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.852); catalogued as COSV99528030; called by muse, mutect2, varscan2
- CAMTA1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57887236, COSV57906544; called by muse, mutect2, varscan2
- CAPZA1 | c.77del p.P26Qfs*40 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV54147680; called by mutect2, pindel, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CASP8AP2 | c.5190G>T p.Q1730H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV99387130; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs759258977; called by mutect2, varscan2
- CCL1 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV99861753; called by mutect2, varscan2
- CCL11 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100005607; called by muse, mutect2, varscan2
- CDC37 | c.284A>C p.E95A | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.282); catalogued as COSV99705794; called by muse, mutect2, varscan2
- CDHR2 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991743; called by muse, mutect2
- CDHR3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.134); catalogued as rs373691451, COSV58418534; called by muse, mutect2, varscan2
- CDKL5 | c.1681A>G p.T561A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV101184369; called by muse, mutect2, varscan2
- CDRT4 | c.341T>C p.M114T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs745848525, COSV100381567; called by muse, mutect2, varscan2
- CEBPE | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99247591; called by muse, mutect2, varscan2
- CELSR1 | c.8239G>A p.G2747R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs771193237, COSV99418669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as rs776824429; called by pindel, varscan2
- CENPU | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99859985; called by muse, mutect2
- CEP126 | c.82dup p.L28Pfs*46 | Frame Shift Ins (INS) | VAF 16/69 reads (23%) | catalogued as rs757955230; called by mutect2, pindel, varscan2
- CFAP43 | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs768248089, COSV99530802; called by muse, mutect2, varscan2
- CFAP44 | c.2139G>T p.E713D | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV55615114; called by muse, mutect2, varscan2
- CFP | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901502; called by muse, mutect2
- CHD6 | c.4645C>T p.R1549* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV64695652; called by muse, mutect2, varscan2
- CHRM1 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs777577586, COSV100186213; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs751548647; called by mutect2, varscan2
- CNTNAP5 | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757718414, COSV70471861; called by muse, mutect2, varscan2
- COQ3 | c.938C>A p.S313* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99632786; called by muse, mutect2, varscan2
- COX5B | c.147G>C p.R49S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV99300284; called by muse, mutect2, varscan2
- CPSF1 | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99433455; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs747248693; called by mutect2, varscan2
- CSRP2 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as rs750932703, COSV100222752; called by muse, mutect2, varscan2
- CT83 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); catalogued as rs1556695294, COSV100902592; called by muse, mutect2, varscan2
- CTNNA1 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1274345685, COSV57070748, COSV57077454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CWC22 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV55426694; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs775988957; called by mutect2, pindel, varscan2
- CYP51A1 | c.1026dup p.C343Mfs*19 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | catalogued as rs746385504; called by mutect2, varscan2
- DCAF11 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182483204, COSV100386727, COSV58110320; called by muse, mutect2, varscan2
- DCC | c.1006C>A p.H336N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as COSV100498471, COSV59117984; called by muse, mutect2, varscan2
- DCLK1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV99711705, COSV99713000; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX18 | c.1207-1G>T p.X403_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV54305352; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX51 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778219271, COSV100223093; called by muse, mutect2, varscan2
- DEFB110 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as rs759919856, COSV101182487; called by muse, mutect2, varscan2
- DENND3 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs764136800, COSV99371129; called by muse, mutect2, varscan2
- DISP3 | c.2443C>A p.P815T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV99608948; called by muse, mutect2, varscan2
- DLGAP1 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV59809839; called by muse, mutect2, varscan2
- DNAAF6 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100314526; called by muse, mutect2, varscan2
- DNAH1 | c.4730G>A p.G1577D | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101326126; called by muse, mutect2, varscan2
- DNAH10 | c.7322T>G p.V2441G (on ENST00000409039; = p.V2380G on NM_207437.3) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101292331; called by muse, mutect2, varscan2
- DNAH11 | c.10738C>T p.R3580C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs72657399; called by muse, mutect2, varscan2
- DNAH2 | c.9271G>A p.A3091T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101209411; called by muse, mutect2, varscan2
- DNAJC16 | c.574+1G>A p.X192_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV101012595; called by muse, mutect2, varscan2
- DNMT3B | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.009); catalogued as COSV52422344, COSV99142130; called by muse, mutect2, varscan2
- DOCK8 | c.4462C>G p.L1488V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs763192893, COSV66621711; called by muse, mutect2, varscan2
- DST | c.18499C>G p.L6167V (on ENST00000361203 / NM_001374722.1; = p.L3864V on NM_015548.5) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99757310; called by muse, mutect2
- DTD2 | c.205T>A p.L69I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV100180095; called by muse, mutect2, varscan2
- ECPAS | c.4012A>G p.I1338V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs747003887, COSV99398502; called by muse, mutect2, varscan2
- EDAR | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.433); catalogued as rs1244221558, COSV99303795; called by muse, mutect2, varscan2
- EEF2 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58579461; called by muse, mutect2, varscan2
- EEFSEC | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs367956823, COSV99630581; called by muse, mutect2, varscan2
- EIF3E | c.462del p.F154Lfs*13 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs1554600455; called by mutect2, pindel, varscan2
- ELOVL4 | c.182G>T p.W61L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV100876311; called by muse, mutect2, varscan2
- ELP6 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs759438726, COSV56132217; called by muse, mutect2, varscan2
- ENTPD6 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1260998416, COSV100737103; called by muse, mutect2, varscan2
- EPM2AIP1 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99212499; called by muse, mutect2, varscan2
- EPOR | c.1506del p.S503Afs*13 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs752862659; called by mutect2, pindel, varscan2
- EPPK1 | c.5002C>T p.Q1668* | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as COSV101599872; called by muse, mutect2, varscan2
- EZHIP | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs377315415, COSV100539551; called by muse, mutect2, varscan2
- F2 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs775021214, COSV100319556; called by muse, varscan2
- F5 | c.5340G>T p.K1780N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100889143; called by muse, mutect2, varscan2
- FAM131A | c.934C>T p.R312W (on ENST00000310585; = p.R343W on NM_144635.5) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1177537514, COSV99658667; called by muse, mutect2, varscan2
- FAM131C | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100989726; called by muse, mutect2, varscan2
- FAM47A | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60500739; called by muse, mutect2, varscan2
- FAT1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs547340067, COSV71672032; called by muse, mutect2, varscan2
- FAT2 | c.4955C>A p.P1652H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV99943237; called by muse, mutect2, varscan2
- FBN1 | c.6709G>A p.V2237M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs764218640, COSV100355445; called by muse, mutect2, varscan2
- FCGRT | c.416A>C p.E139A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV99675311; called by muse, mutect2, varscan2
- FHOD1 | c.3087dup p.S1030Qfs*19 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | catalogued as rs762098881; called by mutect2, pindel, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FMN1 | c.4067A>T p.Y1356F (on ENST00000616417 / NM_001277313.2; = p.Y1133F on NM_001103184.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV100568822; called by muse, varscan2
- FMN1 | c.4001A>T p.Y1334F (on ENST00000616417 / NM_001277313.2; = p.Y1111F on NM_001103184.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.429); catalogued as COSV100568823; called by muse, varscan2
- FOXD4L4 | c.330del p.Y111Tfs*52 | Frame Shift Del (DEL) | VAF 22/134 reads (16%) | catalogued as rs1350980242; called by mutect2, varscan2
- FTO | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.174); catalogued as COSV99193146; called by muse, mutect2, varscan2
- G2E3 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52838287, COSV99249710; called by muse, mutect2, varscan2
- GAL3ST3 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs747506204, COSV61749535; called by muse, mutect2, varscan2
- GALNT5 | c.2195C>A p.S732Y | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs755858697, COSV99375058, COSV99375283; called by muse, mutect2, varscan2
- GAN | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as COSV101634001; called by muse, mutect2, varscan2
- GCKR | c.286-2A>G p.X96_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99253927; called by muse, mutect2, varscan2
- GEN1 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs371047592; called by muse, mutect2
- GIGYF2 | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as COSV101004429; called by muse, mutect2, varscan2
- GMPPA | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754071645, COSV58006109, COSV58008432; called by muse, mutect2, varscan2
- GOLGA2 | c.318C>A p.T106= | Splice Region (SNP) | VAF 29/47 reads (62%) | catalogued as COSV101425900; called by muse, mutect2, varscan2
- GP5 | c.113del p.G38Afs*9 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs750629635; called by mutect2, pindel, varscan2
- GPAT4 | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101214034; called by mutect2, varscan2
- GPR180 | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV100979057; called by muse, mutect2, varscan2
- GPRC5B | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100315153; called by muse, mutect2, varscan2
- GRID1 | c.1738A>G p.I580V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.166); catalogued as COSV100024517; called by muse, mutect2
- GRIN2A | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs267604688, COSV58032774; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as rs754199513; called by mutect2, varscan2
- GSPT2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.178); catalogued as COSV100468212; called by muse, mutect2, varscan2
- HAS1 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV99708445; called by muse, mutect2
- HCAR2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); catalogued as rs201097098, COSV61024973; called by muse, mutect2, varscan2
- HCFC1 | c.358T>C p.W120R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100129276; called by muse, mutect2, varscan2
- HDAC4 | c.2703dup p.M902Hfs*5 | Frame Shift Ins (INS) | VAF 19/44 reads (43%) | catalogued as rs747537946; called by mutect2, varscan2
- HDGFL1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV57751109; called by muse, mutect2, varscan2
- HECTD1 | c.6563C>T p.T2188I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV101237414; called by muse, mutect2, varscan2
- HECTD4 | c.4721A>C p.K1574T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.944); catalogued as COSV101107768; called by muse, mutect2, varscan2
- HERC2 | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55340686, COSV55352753; called by muse, mutect2, varscan2
- HERC4 | c.2137G>A p.V713M (on ENST00000395198 / NM_022079.3; = p.V705M on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99517095; called by muse, mutect2, varscan2
- HMG20B | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.804); catalogued as COSV99503104; called by muse, mutect2, varscan2
- HMX2 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100378785; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXD3 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV50879687; called by muse, mutect2, varscan2
- HR | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs771639271, COSV100455869; called by muse, mutect2, varscan2
- HSP90B1 | c.2364A>T p.E788D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55356294; called by muse, mutect2, varscan2
- HTR3A | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55471054; called by muse, varscan2
- HYDIN | c.6443G>T p.G2148V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59255408; called by muse, mutect2, varscan2
- IGSF3 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100604825; called by muse, mutect2, varscan2
- IGSF3 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100604827; called by muse, mutect2, varscan2
- IL31RA | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0.091); catalogued as rs201982561, COSV100732716; called by muse, mutect2, varscan2
- INO80E | c.406_408del p.S136del | In Frame Del (DEL) | VAF 25/85 reads (29%) | catalogued as rs1161955258; called by pindel, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs760925109; called by mutect2, pindel
- INSM2 | c.1589G>A p.C530Y | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99355082; called by muse, mutect2, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as rs779930616; called by mutect2, pindel
- INTS1 | c.746T>C p.F249S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101247991; called by muse, mutect2, varscan2
- INTS3 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100016157; called by muse, mutect2, varscan2
- JADE3 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs782548118, COSV54464940; called by muse, mutect2, varscan2
- JAG2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446530594, COSV59312707; called by muse, mutect2, varscan2
- KCNK10 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs771917656, COSV56640159, COSV56643228; called by muse, mutect2, varscan2
- KCTD20 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs773842819, COSV99536029, COSV99536047; called by muse, mutect2, varscan2
- KDM4B | c.2903G>A p.S968N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs746604190, COSV99346617; called by muse, mutect2, varscan2
- KIAA1210 | c.1611G>T p.W537C | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101274242; called by muse, mutect2, varscan2
- KIAA1328 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs376208853; called by muse, mutect2, varscan2
- KIAA1549 | c.5792T>C p.I1931T (on ENST00000422774 / NM_001164665.2; = p.I1915T on NM_020910.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99651035; called by muse, mutect2
- KIF5A | c.2987A>T p.D996V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99673121; called by muse, mutect2, varscan2
- KLHL38 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs375307692; called by muse, mutect2, varscan2
- KMT2C | c.13841G>A p.R4614K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV100072835; called by muse, mutect2, varscan2
- KMT2D | c.12340G>T p.G4114* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99982899; called by muse, mutect2, varscan2
- KRT2 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs200877905, COSV100548514; called by muse, mutect2, varscan2
- KRT5 | c.1478T>C p.V493A | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV99358072; called by muse, mutect2, varscan2
- KRT85 | c.1125G>T p.E375D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV57738216; called by muse, mutect2, varscan2
- LANCL2 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV99634878; called by muse, mutect2, varscan2
- LCOR | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs773115783, COSV100603657; called by muse, mutect2, varscan2
- LDHB | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV100636424; called by muse, mutect2, varscan2
- LENG8 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs770711332, COSV58726873; called by muse, mutect2, varscan2
- LGALS8 | c.652C>A p.L218I (on ENST00000341872; = p.L260I on NM_006499.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99436529; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.2596G>T p.V866F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs759100014, COSV99183544; called by muse, mutect2, varscan2
- LRFN1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99953029; called by muse, mutect2
- LRP10 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100612406; called by muse, mutect2, varscan2
- LRP4 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV101066670; called by muse, mutect2, varscan2
- LRRC37A3 | c.3008C>T p.T1003I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV100141108; called by muse, mutect2
- LRRIQ4 | c.1331A>G p.Q444R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs750645330, COSV100540277; called by muse, mutect2
- LTN1 | c.4208A>G p.H1403R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV100798030; called by muse, mutect2, varscan2
- LYST | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101089728; called by muse, mutect2, varscan2
- MAK | c.1087_1088del p.Q364Gfs*18 | Frame Shift Del (DEL) | VAF 68/163 reads (42%) | catalogued as rs1196153507; called by pindel, varscan2
- MAMDC4 | c.1505del p.G502Afs*41 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs1474597626; called by mutect2, pindel, varscan2
- MAN2B1 | c.1786A>G p.I596V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1000868549, COSV99667050; called by muse, varscan2
- MAN2B1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs1374305848, COSV99667052; called by muse, varscan2
- MAN2B2 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99577573; called by mutect2, varscan2
- MAP2K7 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67607651; called by muse, mutect2, varscan2
- MAP3K4 | c.4103T>C p.L1368P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815463; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2182G>T p.G728* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99169257; called by muse, mutect2
- MAST4 | c.7556A>G p.D2519G (on ENST00000403625 / NM_001164664.2; = p.D2330G on NM_015183.3) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV99844529; called by muse, mutect2, varscan2
- MDC1 | c.6182C>T p.S2061L | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773327966, COSV100902864; called by muse, mutect2, varscan2
- MDM1 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs368040136; called by muse, mutect2, varscan2
- MEAK7 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640407; called by muse, mutect2, varscan2
- MFAP3L | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100852683; called by muse, mutect2, varscan2
- MFSD14B | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64700701; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs762448666; called by mutect2, pindel
- MISP | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771927186, COSV53119294; called by muse, mutect2, varscan2
- MLLT10 | c.2015G>A p.R672H (on ENST00000307729 / NM_001195626.3; = p.R688H on NM_004641.3) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs755064344, COSV57001460; called by muse, mutect2, varscan2
- MMP13 | c.1000A>G p.I334V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs782377946, COSV99506616; called by muse, mutect2
- MMS22L | c.516T>G p.D172E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99247148; called by muse, mutect2, varscan2
- MORC2 | c.2520C>T p.R840= (on ENST00000397641 / NM_001303256.3; = p.R778= on NM_014941.3) | Splice Region (SNP) | VAF 12/33 reads (36%) | catalogued as rs748062673, COSV99310001; called by muse, mutect2, varscan2
- MS4A3 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs780015751, COSV53934738; called by muse, mutect2, varscan2
- MSH5 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755055223, COSV65211574; called by muse, mutect2, varscan2
- MST1R | c.1855C>A p.L619M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV99618976; called by muse, mutect2, varscan2
- MTF1 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100888654; called by muse, mutect2, varscan2
- MTHFD1 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV99387000; called by muse, mutect2, varscan2
- MYH1 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs749373460, COSV56847132; called by muse, mutect2, varscan2
- MYH10 | c.5429C>T p.S1810F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99345465; called by muse, mutect2, varscan2
- MYH2 | c.4135A>G p.T1379A | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV99820361; called by muse, mutect2, varscan2
- MYH6 | c.991A>G p.M331V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100676688; called by muse, mutect2, varscan2
- MYH7B | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs776179958, COSV53418178; called by muse, mutect2, varscan2
- MYH7B | c.3763G>A p.V1255M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as rs1305387914, COSV99328503; called by muse, mutect2
- MYO15A | c.3584T>C p.V1195A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1358012753, COSV99233201; called by mutect2, varscan2
- MYO1C | c.1400C>T p.A467V (on ENST00000648651 / NM_001080779.2; = p.A432V on NM_033375.5) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs778512232, COSV62998333; called by muse, mutect2, varscan2
- MYO7A | c.4312G>A p.A1438T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs575760892, COSV68683265; called by muse, mutect2, varscan2
- MYOM1 | c.3944C>T p.T1315M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748195985, COSV55304745; called by muse, mutect2, varscan2
- MYRF | c.789dup p.S264Qfs*74 (on ENST00000278836 / NM_001127392.3; = p.S255Qfs*74 on NM_013279.4) | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs769274302; called by mutect2, varscan2
- NCAPD2 | c.2275C>T p.R759W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs749966496, COSV100217270; called by muse, varscan2
- NCOA3 | c.3872G>A p.S1291N (on ENST00000371998 / NM_181659.3; = p.S1287N on NM_006534.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV100507684; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | catalogued as rs747914168; called by mutect2, varscan2
- NEK9 | c.2486C>A p.S829Y | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1341860275, COSV99464183; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFKB2 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99503087; called by muse, mutect2, varscan2
- NMBR | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57801915; called by muse, mutect2, varscan2
- NME8 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99553440; called by muse, mutect2, varscan2
- NR4A3 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as rs1391653942, COSV58245523; called by muse, mutect2, varscan2
- NR5A1 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.368); catalogued as COSV101007703; called by muse, mutect2
- NSD1 | c.4305C>A p.C1435* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | catalogued as COSV61772466; called by muse, mutect2
- NSD1 | c.5301C>T p.Y1767= | Splice Region (SNP) | VAF 15/30 reads (50%) | catalogued as rs1241312522, COSV100729364; called by muse, mutect2, varscan2
- NTM | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100868754; called by muse, mutect2, varscan2
- NTRK3 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs774739739, COSV100446846; called by muse, mutect2, varscan2
- NUP210L | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as rs1179865434, COSV55153062; called by muse, mutect2, varscan2
- OBSCN | c.5584G>A p.V1862M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.903); catalogued as rs764613872, COSV52777658; called by muse, mutect2, varscan2
- OBSCN | c.17902G>A p.A5968T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs550023461, COSV52736713; called by muse, mutect2, varscan2
- OCLN | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV100783830; called by muse, mutect2, varscan2
- OPN1SW | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99975717; called by muse, mutect2, varscan2
- OR1K1 | c.852del p.M285Cfs*2 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs750058621; called by mutect2, pindel, varscan2
- OR2A25 | c.530del p.F177Sfs*20 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as rs763117243; called by mutect2, pindel, varscan2
- OR52B2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101603951; called by muse, mutect2, varscan2
- OR6Q1 | c.646A>G p.M216V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs887879779, COSV100110076; called by muse, mutect2
- OVCH1 | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100548685; called by muse, mutect2, varscan2
- PAG1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1288624721, COSV99597425; called by muse, mutect2, varscan2
- PAPPA2 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs760380892, COSV62788181; called by muse, mutect2, varscan2
- PAQR8 | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100658482; called by muse, mutect2
- PCDH12 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51525754; called by muse, mutect2, varscan2
- PCDHA12 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV56520545; called by muse, varscan2
- PCDHA4 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782615790, COSV63546017; called by muse, mutect2
- PCDHA4 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as COSV100793548; called by muse, mutect2, varscan2
- PCDHB9 | c.1176del p.L393* | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | catalogued as rs782200278; called by mutect2, pindel, varscan2
- PCDHGA6 | c.1682A>C p.E561A | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); catalogued as COSV99540143; called by muse, mutect2, varscan2
- PCMTD2 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100204203; called by muse, mutect2, varscan2
- PCSK1 | c.2164A>G p.N722D | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.038); catalogued as COSV100227143; called by muse, varscan2
- PDK1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs756942072, COSV56374996; called by muse, mutect2, varscan2
- PER2 | c.3113G>A p.R1038H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs780467105, COSV99612110; called by muse, mutect2, varscan2
- PER3 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as COSV100728377; called by muse, mutect2, varscan2
- PEX5L | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55841215; called by muse, mutect2
- PHKA2 | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs765823035, COSV66057411; called by muse, mutect2, varscan2
- PIGQ | c.733_734del p.S245Hfs*69 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs780581800; called by pindel, varscan2
- PIK3CG | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV100782950; called by muse, mutect2, varscan2
- PIK3R2 | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99717474; called by muse, mutect2, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs746999253; called by mutect2, varscan2
- PLK4 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV54637290; called by muse, mutect2, varscan2
- PLXNA2 | c.1312T>A p.Y438N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100885569; called by muse, mutect2, varscan2
- PNKP | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99681816; called by muse, mutect2, varscan2
- POLA1 | c.3722T>A p.L1241H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100985529; called by muse, mutect2, varscan2
- PRAG1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs370347554; called by muse, mutect2, varscan2
- PRDX6 | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV100458451, COSV100458499; called by muse, mutect2, varscan2
- PREX1 | c.689T>C p.M230T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100906461; called by muse, mutect2
- PRKCSH | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs147655486; called by muse, mutect2, varscan2
- PSEN2 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV100423121; called by muse, mutect2, varscan2
- PSG9 | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV99392361; called by muse, mutect2, varscan2
- PTPN14 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145779086; called by muse, mutect2, varscan2
- PTPRG | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs764140516, COSV55650697, COSV55660767; called by muse, mutect2, varscan2
- PTPRN2 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101234595; called by muse, mutect2, varscan2
- PYGM | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775556109, COSV99377211; called by muse, mutect2, varscan2
- PYGM | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as rs140731551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QSER1 | c.4784T>A p.L1595H (on ENST00000399302; = p.L1724H on NM_001076786.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101234875; called by muse, mutect2
- RAB3GAP1 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV99921256; called by muse, mutect2, varscan2
- RAB5A | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99811025; called by muse, mutect2, varscan2
- RANBP3L | c.480+2T>C p.X160_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99683860; called by muse, mutect2
- RAPGEF1 | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.638); catalogued as rs762417571, COSV64700165; called by muse, mutect2, varscan2
- RASSF7 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs541192906, COSV100272645; called by muse, mutect2, varscan2
- REV3L | c.6504A>G p.I2168M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV100725308; called by muse, mutect2, varscan2
- RGL2 | c.1801C>A p.L601I | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.824); catalogued as COSV101004805; called by muse, mutect2, varscan2
- RHOA | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV101371136; called by muse, mutect2, varscan2
- RIOX1 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.475); catalogued as COSV100408054; called by muse, mutect2, varscan2
- RNF151 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs375938267, COSV100364493; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROR2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as rs1305604353, COSV100995876; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTL5 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as rs769386611, COSV101029809, COSV65453888; called by muse, mutect2, varscan2
- RYR1 | c.3951del p.A1318Pfs*80 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs772166066; called by mutect2, pindel
- RYR2 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs376243998, COSV100770737; called by muse, mutect2
- SACS | c.8017G>T p.D2673Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as COSV101207503; called by muse, mutect2
- SAMD11 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1403306757, COSV100574662; called by muse, mutect2
- SETD1A | c.4783A>G p.I1595V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV99353193; called by muse, mutect2, varscan2
- SGTA | c.740T>G p.M247R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV99682591; called by muse, mutect2, varscan2
- SIM1 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492457; called by muse, mutect2, varscan2
- SIMC1 | c.2204G>A p.R735H (on ENST00000443967 / NM_001308196.1; = p.R320H on NM_198567.5) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs374328101; called by muse, mutect2, varscan2
- SIRT6 | c.80del p.P27Rfs*133 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs766524945, COSV59446625; called by mutect2, pindel, varscan2
- SLC1A2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145275821; called by muse, mutect2, varscan2
- SLC29A4 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1327577092, COSV99786831; called by muse, mutect2, varscan2
- SLC44A2 | c.1979A>G p.Y660C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1023184660, COSV100213266; called by muse, mutect2, varscan2
- SLC45A4 | c.1325G>A p.R442H (on ENST00000517878 / NM_001286646.2; = p.R391H on NM_001080431.2) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs541950867, COSV50175602; called by muse, mutect2, varscan2
- SLC8A1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765590704, COSV100244497; called by muse, varscan2
- SLC9A9 | c.1192C>A p.L398I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100341264; called by muse, mutect2, varscan2
- SLC9B1 | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV99599705; called by muse, mutect2, varscan2
- SMG5 | c.1710G>A p.M570I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV100700810; called by muse, mutect2, varscan2
- SMYD3 | c.1085del p.F362Sfs*12 (on ENST00000490107 / NM_001375962.1; = p.F303Sfs*12 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as COSV63628704; called by mutect2, pindel, varscan2
- SP100 | c.2180A>G p.H727R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100414073; called by muse, mutect2, varscan2
- SPAG17 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1201454411, COSV60461015; called by muse, mutect2, varscan2
- SPATS1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs770092134, COSV99913442; called by muse, mutect2, varscan2
- SPG11 | c.1476T>G p.I492M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV99968883; called by muse, mutect2, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPPL2C | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1374073210, COSV61293763; called by muse, mutect2, varscan2
- SPTA1 | c.4804A>C p.K1602Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100935115; called by muse, mutect2, varscan2
- SRBD1 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.333); catalogued as COSV99765142; called by muse, mutect2, varscan2
- SRRM4 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs199609864; called by muse, mutect2, varscan2
- SRSF6 | c.991C>A p.R331S | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as COSV99719748; called by muse, mutect2, varscan2
- STAT2 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs766795191, COSV100028961; called by muse, mutect2, varscan2
- STK38 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100007361; called by muse, mutect2, varscan2
- STRIP1 | c.2400G>T p.Q800H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.472); catalogued as COSV100874085; called by muse, mutect2, varscan2
- STRN3 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100670682; called by muse, mutect2, varscan2
- STXBP6 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs747548510, COSV100121890; called by muse, mutect2, varscan2
- SULF2 | c.830A>G p.N277S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs994017040, COSV100737238; called by muse, mutect2, varscan2
- SUZ12 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.307); catalogued as rs1238004928, COSV100496927; called by muse, mutect2, varscan2
- SYMPK | c.3253del p.H1085Tfs*11 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs749354800; called by mutect2, pindel, varscan2
- SYNE1 | c.1918G>T p.E640* (on ENST00000367255 / NM_182961.4; = p.E647* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99567726; called by muse, mutect2, varscan2
- SYT16 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs755013221, COSV70857964; called by muse, mutect2, varscan2
- TAB3 | c.2111A>G p.E704G | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99916351; called by muse, mutect2, varscan2
- TECTA | c.4379A>G p.D1460G | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.423); catalogued as rs920273300, COSV99880196; called by muse, mutect2, varscan2
- TEX43 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100847478; called by muse, mutect2, varscan2
- THRB | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54982311; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TMEM94 | c.3433dup p.H1145Pfs*2 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | catalogued as rs752158523; called by mutect2, varscan2
- TNIP1 | c.1634G>A p.C545Y | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV100161451; called by muse, mutect2, varscan2
- TRPV3 | c.259del p.Q87Sfs*7 | Frame Shift Del (DEL) | VAF 24/48 reads (50%) | catalogued as rs911130511, COSV100027514; called by mutect2, varscan2
- TSBP1 | c.853A>G p.I285V (on ENST00000617061; = p.I288V on NM_006781.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV100898833; called by muse, mutect2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTLL7 | c.726C>A p.T242= | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99552546; called by muse, mutect2
- TTN | c.94123A>G p.T31375A (on ENST00000591111; = p.T23951A on NM_003319.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | PolyPhen possibly damaging (0.457); catalogued as COSV100617607; called by muse, mutect2, varscan2
- TTN | c.25613G>T p.G8538V (on ENST00000591111; = p.G7611V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | PolyPhen probably damaging (1); catalogued as rs767057972, COSV100617610; called by mutect2, varscan2
- TXLNB | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100625009; called by muse, mutect2, varscan2
- TXNDC16 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99909292; called by muse, mutect2, varscan2
- TXNDC8 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100995670; called by muse, mutect2, varscan2
- TXNRD2 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100538863; called by muse, mutect2, varscan2
- UBE2A | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.988); catalogued as COSV100660513; called by muse, mutect2
- UBE2O | c.2416G>A p.G806R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs370506474; called by muse, mutect2, varscan2
- UBE2R2 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99602278; called by muse, mutect2, varscan2
- UBQLNL | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66494275, COSV66494382; called by muse, mutect2, varscan2
- UNC5B | c.2819C>G p.A940G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV100100858; called by muse, mutect2, varscan2
- UPF3B | c.674_677del p.R225Kfs*22 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs794727881; called by pindel, varscan2
- USP40 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1200121924, COSV99296571; called by muse, mutect2, varscan2
- USP42 | c.1310T>G p.I437S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100084590; called by muse, mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs762976381; called by mutect2, varscan2
- VCP | c.2314A>G p.R772G | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV100734244; called by muse, mutect2, varscan2
- VEGFC | c.486T>G p.C162W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99709898; called by muse, mutect2, varscan2
- WDR24 | c.2185G>A p.G729S (on ENST00000248142; = p.G599S on NM_032259.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs1402263816, COSV99555796; called by muse, mutect2, varscan2
- WDR25 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100091903; called by muse, mutect2, varscan2
- WDR35 | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV99853249; called by muse, mutect2, varscan2
- WDR44 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99561635; called by muse, mutect2, varscan2
- WDR6 | c.2820C>A p.S940R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100556501; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK2 | c.961C>A p.H321N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942986; called by muse, mutect2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- WWC3 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367881383, COSV66501866; called by muse, mutect2, varscan2
- XAB2 | c.658-1G>A p.X220_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100601737; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs762052135; called by mutect2, varscan2
- YAF2 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100586334; called by muse, mutect2, varscan2
- YTHDC1 | c.2095C>T p.R699* (on ENST00000344157 / NM_001031732.4; = p.R681* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV60008841; called by mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs751577786; called by mutect2, varscan2
- ZC3H7A | c.2047C>A p.Q683K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100865543; called by muse, mutect2, varscan2
- ZDHHC11 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV99363007; called by muse, mutect2, varscan2
- ZFAND6 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99928721; called by muse, mutect2
- ZFHX3 | c.2758G>A p.G920R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376414532; called by muse, mutect2, varscan2
- ZKSCAN2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs371020193; called by muse, mutect2, varscan2
- ZNF232 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV100005715, COSV51504889; called by muse, mutect2, varscan2
- ZNF514 | c.1195del p.T399Pfs*21 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs755697811; called by mutect2, varscan2
- ZNF536 | c.3050C>T p.A1017V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100835339; called by muse, mutect2, varscan2
- ZNF536 | c.3649C>G p.P1217A | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV100834881, COSV100835340; called by muse, mutect2, varscan2
- ZNF574 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs769648256, COSV55903575; called by muse, mutect2, varscan2
- ZNF648 | c.1570C>T p.R524* | Nonsense Mutation (SNP) | VAF 24/101 reads (24%) | catalogued as COSV100374639; called by muse, mutect2, varscan2
- ZNF654 | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as COSV100525796; called by muse, mutect2, varscan2
- ZNF668 | c.1543del p.Q515Sfs*14 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs760397907; called by mutect2, pindel, varscan2
- ZNF676 | c.1793G>A p.C598Y (on ENST00000650058; = p.C566Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101236240; called by muse, mutect2, varscan2
- ZNF786 | c.1613A>G p.Q538R | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV100302894; called by muse, mutect2, varscan2
- AACS | c.1486dup p.T496Nfs*7 | Frame Shift Ins (INS) | VAF 42/126 reads (33%) | called by mutect2, pindel, varscan2
- AC109583.1 | c.136del p.A46Rfs*104 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- ADAL | c.276del p.E93Nfs*12 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- AGO1 | c.575del p.G192Vfs*20 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ARAP1 | c.962del p.G321Afs*30 (on ENST00000393609 / NM_001040118.2; = p.G76Afs*30 on NM_015242.4) | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.140_154del p.A47_L52delinsV | In Frame Del (DEL) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- ATP2B4 | c.261del p.K89Sfs*6 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- ATP2C1 | c.2454dup p.D819* | Frame Shift Ins (INS) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- ATXN1 | c.1540dup p.Q514Pfs*23 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by pindel, varscan2
- CAMKK1 | c.304del p.R102Gfs*24 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- CAND1 | c.2875_2878del p.T959* | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by pindel, varscan2
- CD200 | c.811dup p.L271Pfs*40 (on ENST00000473539 / NM_001004196.3; = p.L246Pfs*40 on NM_005944.7 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- CEP162 | c.3191del p.N1064Mfs*11 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- CERS2 | c.1054del p.E352Rfs*14 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- COG6 | c.1237dup p.I413Nfs*5 | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, varscan2
- CRMP1 | c.1685del p.P562Lfs*21 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- EIF4G3 | c.1689del p.V564* | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- ESYT3 | c.1220_1222del p.X407_splice | Splice Site (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- F2 | c.-5_9del | Translation Start Site (DEL) | VAF 8/23 reads (35%) | called by pindel, varscan2
- FADS1 | c.790del p.A264Pfs*62 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- FSHR | c.1895del p.N632Tfs*10 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- IGFALS | c.1441del p.L481Cfs*188 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- IL1R1 | c.1251del p.K417Nfs*28 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel
- JCAD | c.1172del p.P391Lfs*9 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- KDM3B | c.2529dup p.K844Efs*11 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- KLF10 | c.109del p.S37Vfs*6 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- MADD | c.851_852del p.L284Pfs*108 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- MAST3 | c.3321del p.G1108Afs*194 | Frame Shift Del (DEL) | VAF 9/16 reads (56%) | called by mutect2, varscan2
- MCUR1 | c.686del p.K229Rfs*3 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- MORC1 | c.388del p.S130Lfs*14 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- MYO1F | c.837dup p.I280Dfs*11 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel
- NAT8 | c.592del p.Q198Sfs*10 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- NCOR2 | c.3140dup p.C1048Lfs*14 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- NHLRC2 | c.1456del p.R486Gfs*27 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- NR3C1 | c.453del p.T152Qfs*19 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- NSRP1 | c.347del p.K116Rfs*29 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- OTUD6B | c.783dup p.P262Tfs*18 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- PCGF6 | c.614-3del | Splice Region (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- PGR | c.1770_1772del p.F591del | In Frame Del (DEL) | VAF 17/39 reads (44%) | called by pindel, varscan2
- PHB2 | c.711_711+2del p.X237_splice | Splice Site (DEL) | VAF 12/29 reads (41%) | called by pindel, varscan2
- PIGR | c.1189del p.L397Cfs*46 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- PIWIL2 | c.1828del p.Y610Tfs*19 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- PPP3CC | c.1063del p.E355Kfs*8 | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | called by mutect2, pindel, varscan2
- PROS1 | c.458del p.K153Sfs*6 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- PSPC1 | c.1535dup p.N513Qfs*3 | Frame Shift Ins (INS) | VAF 26/120 reads (22%) | called by mutect2, pindel, varscan2
- PTEN | c.170dup p.L57Ffs*6 | Frame Shift Ins (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC36A2 | c.76del p.S26Vfs*23 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- SPATA22 | c.1021dup p.T341Nfs*12 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | called by pindel, varscan2
- SRSF2 | c.20del p.P7Lfs*7 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- ST3GAL5 | c.289del p.M97Cfs*9 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- STK36 | c.1058T>C p.L353P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.361); called by muse, mutect2
- SUSD4 | c.1235del p.P412Qfs*51 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- TLL2 | c.740dup p.V248Gfs*6 | Frame Shift Ins (INS) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- TMEM170B | c.17del p.G6Afs*5 | Frame Shift Del (DEL) | VAF 36/65 reads (55%) | called by mutect2, pindel, varscan2
- TNRC6B | c.1124del p.N375Mfs*7 | Frame Shift Del (DEL) | VAF 16/18 reads (89%) | called by mutect2, varscan2
- ZC3H15 | c.441del p.D148Ifs*14 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- ZNF44 | c.766del p.W256Gfs*34 (on ENST00000356109 / NM_001164276.2; = p.W208Gfs*34 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- ACACA | c.2556A>G p.L852= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- ACAN | c.549C>T p.A183= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100718337; called by muse, mutect2, varscan2
- AGXT2 | c.1116G>A p.A372= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs1207970057, COSV51485094; called by muse, mutect2, varscan2
- AKT3 | c.972C>T p.G324= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99794442, COSV99795689; called by muse, mutect2, varscan2
- ALG6 | c.462A>G p.P154= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99673281; called by muse, mutect2, varscan2
- ALS2CL | c.1221C>T p.D407= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100015100; called by muse, mutect2, varscan2
- ANKS6 | c.1806C>T p.G602= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs748051310, COSV62048798; called by muse, mutect2, varscan2
- AOC3 | c.639G>A p.T213= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs756384382, COSV99520205; called by muse, mutect2, varscan2
- ASB11 | c.363T>A p.G121= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100729057; called by muse, mutect2, varscan2
- BAIAP2L1 | c.822C>T p.Y274= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs756426782, COSV50055242; called by muse, mutect2, varscan2
- BIRC3 | c.1647G>A p.R549= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99680002; called by muse, mutect2, varscan2
- BTBD11 | c.2223C>T p.H741= (on ENST00000280758 / NM_001018072.2; = p.H278= on NM_001017523.2) | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs768623532, COSV55026509; called by muse, mutect2, varscan2
- BTBD7 | c.195C>T p.T65= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100108060; called by muse, mutect2, varscan2
- C3 | c.2922C>T p.T974= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs139152390; called by muse, mutect2, varscan2
- C4B | c.3330G>A p.Q1110= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as COSV101312258; called by muse, mutect2, varscan2
- CCAR1 | c.2352C>T p.V784= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1026109743, COSV56276207; called by muse, mutect2, varscan2
- CD101 | c.1311T>A p.G437= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99869784; called by muse, mutect2, varscan2
- CD2AP | c.837C>A p.A279= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100830467; called by muse, mutect2, varscan2
- CDHR2 | c.24C>T p.C8= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99991736; called by muse, mutect2
- CDHR2 | c.858C>T p.P286= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs746333936, COSV99991738; called by muse, mutect2, varscan2
- CDON | c.3708C>T p.S1236= (on ENST00000392693 / NM_001243597.2; = p.S1213= on NM_016952.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99701515; called by muse, mutect2, varscan2
- CEBPZ | c.87T>C p.D29= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99135607; called by muse, mutect2, varscan2
- CLSTN1 | c.516G>A p.T172= (on ENST00000377298 / NM_001009566.3; = p.T162= on NM_014944.4) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs763665400, COSV100790621; called by muse, mutect2, varscan2
- CNBP | c.486C>T p.G162= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV69654602, COSV69654965; called by muse, mutect2, varscan2
- CNTN2 | c.2793G>A p.K931= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100085134; called by muse, mutect2, varscan2
- CORO1A | c.705G>A p.L235= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV99532061; called by muse, mutect2, varscan2
- CORO1C | c.423G>T p.T141= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99776015; called by muse, mutect2, varscan2
- CPNE6 | c.981C>T p.H327= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99393512; called by muse, mutect2, varscan2
- CRACD | c.1890G>A p.A630= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs201547934, COSV51731758; called by muse, varscan2
- DCAF1 | c.2133G>A p.L711= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100244531; called by muse, mutect2, varscan2
- DGKQ | c.321G>A p.P107= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs780672484, COSV99892844; called by muse, varscan2
- DMPK | c.1842C>T p.G614= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1309853590, COSV99353260; called by muse, varscan2
- DPYD | c.771C>T p.C257= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs754745863, COSV64594846; called by muse, mutect2, varscan2
- DUSP8 | c.291C>T p.S97= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100524410; called by muse, mutect2, varscan2
- EHBP1L1 | c.4248C>T p.N1416= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs113817256, COSV100442235; called by muse, mutect2, varscan2
- ERC1 | c.3273C>T p.N1091= (on ENST00000360905 / NM_178040.4; = p.N1063= on NM_178039.4) | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs753259837, COSV100706172; called by muse, mutect2, varscan2
- EXOC2 | c.1314C>T p.D438= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs758138811, COSV57869533; called by muse, mutect2
- FAAP100 | c.2448C>T p.A816= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs753809355, COSV58369363; called by muse, mutect2, varscan2
- FAM171A1 | c.900G>A p.T300= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs747778479, COSV100968307; called by muse, varscan2
- FANCB | c.1110A>G p.E370= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100146590; called by muse, mutect2, varscan2
- FCGBP | c.2010C>T p.G670= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs752581812; called by muse, mutect2
- FGD1 | c.1848C>T p.N616= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs765697107, COSV100911067; called by muse, mutect2, varscan2
- FHDC1 | c.2355C>T p.C785= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1026719424, COSV99471388; called by muse, mutect2, varscan2
- FN1 | c.1605T>C p.H535= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100117330; called by muse, mutect2, varscan2
- FNBP1 | c.333G>A p.Q111= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100852726; called by muse, mutect2, varscan2
- FRMPD2 | c.1143C>A p.T381= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100563899, COSV59721419; called by muse, mutect2, varscan2
- GDPD2 | c.420C>A p.I140= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100978645, COSV65531833; called by muse, mutect2, varscan2
- GJC1 | c.171G>A p.Q57= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100395187; called by muse, mutect2, varscan2
- GPR156 | c.615C>T p.D205= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs760588049, COSV100251434; called by muse, mutect2, varscan2
- GREB1 | c.4086G>A p.L1362= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99303079; called by muse, mutect2, varscan2
- GRIK2 | c.1788C>T p.N596= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs759061308, COSV100024475, COSV100026918; called by muse, mutect2, varscan2
- GRK6 | c.750C>A p.A250= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100586924; called by muse, mutect2, varscan2
- HCN1 | c.2319G>A p.A773= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100298585; called by muse, mutect2, varscan2
- HIF1A | c.474T>C p.G158= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100048962; called by muse, mutect2, varscan2
- HIVEP3 | c.318G>A p.S106= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs371696795; called by muse, mutect2, varscan2
- HNRNPF | c.1167C>T p.Y389= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs375590998, COSV100563101, COSV61561063; called by muse, mutect2, varscan2
- HTR1A | c.1146C>T p.G382= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV60503747; called by muse, mutect2, varscan2
- IGFALS | c.1173G>A p.L391= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs886051777, COSV99236555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHA2 | c.450G>A p.T150= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs782646375; called by muse, mutect2, varscan2
- IGSF9 | c.642C>T p.S214= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs372593977; called by muse, mutect2, varscan2
- KIF21B | c.843G>A p.K281= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100144657; called by muse, mutect2, varscan2
- KIF4B | c.2608T>C p.L870= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101469305; called by muse, mutect2, varscan2
- KLHDC1 | c.531C>T p.D177= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs772721610, COSV100833563; called by muse, mutect2, varscan2
- KRTAP24-1 | c.282C>A p.P94= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100447452, COSV61089557; called by muse, mutect2, varscan2
- LAMB4 | c.2973C>T p.C991= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99224396; called by muse, mutect2, varscan2
- LBP | c.435C>T p.G145= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99460959; called by muse, mutect2, varscan2
- LENG8 | c.1137G>A p.P379= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs373827414; called by muse, mutect2, varscan2
- MEN1 | c.1695C>T p.G565= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99581148; called by muse, mutect2, varscan2
- MIA2 | c.2310C>T p.F770= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs529369922, COSV54490213, COSV99697265; called by muse, mutect2, varscan2
- MIOX | c.165C>T p.F55= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs748358902, COSV53312862; called by muse, mutect2, varscan2
- MLXIPL | c.798C>T p.P266= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100515397; called by muse, mutect2, varscan2
- MMS22L | c.1905T>C p.F635= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99247138; called by muse, mutect2, varscan2
- MOV10L1 | c.2754G>A p.Q918= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99434084; called by muse, mutect2, varscan2
- MST1R | c.1500G>T p.R500= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99618978; called by muse, mutect2, varscan2
- MUC17 | c.1665T>C p.P555= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100073774; called by muse, mutect2, varscan2
- MYH14 | c.1800G>A p.A600= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99223062, COSV99224573; called by muse, mutect2, varscan2
- MYO10 | c.5280C>T p.V1760= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs1452436080, COSV57027846; called by muse, mutect2, varscan2
- MYOD1 | c.165G>A p.A55= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs143206427; called by muse, mutect2, varscan2
- NAV2 | c.2541C>T p.S847= (on ENST00000396087 / NM_001244963.2; = p.S824= on NM_145117.5) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs568838794, COSV62339516; called by muse, varscan2
- NBPF15 | c.666G>A p.Q222= | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as COSV100977753; called by muse, mutect2, varscan2
- NOL3 | c.36C>A p.I12= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99220536; called by muse, mutect2, varscan2
- NPBWR1 | c.603C>T p.R201= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs1204796855, COSV100488233; called by muse, mutect2, varscan2
- NR2C2 | c.1722C>T p.S574= (on ENST00000393102; = p.S593= on NM_003298.5) | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100038611; called by muse, varscan2
- NSMCE4A | c.1098C>A p.T366= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100940071; called by muse, mutect2, varscan2
- NUP88 | c.2139C>T p.C713= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99336721; called by muse, mutect2, varscan2
- OR2T12 | c.804C>T p.H268= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs140272693; called by muse, mutect2, varscan2
- PAGE5 | c.42G>A p.T14= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV99215774; called by muse, mutect2, varscan2
- PARN | c.1740C>T p.D580= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs754436480, COSV100421063; called by muse, mutect2, varscan2
- PARP14 | c.2391C>A p.V797= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV101506290; called by muse, mutect2, varscan2
- PCDHA12 | c.1725C>T p.G575= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV100251286; called by muse, varscan2
- PCDHB11 | c.1911G>A p.K637= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV100697038; called by muse, mutect2, varscan2
- PCDHB12 | c.1479C>A p.S493= | Silent (SNP) | VAF 9/166 reads (5%) | catalogued as COSV99507389; called by muse, mutect2
- PCNT | c.4087C>T p.L1363= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1166739616, COSV100855629; called by muse, mutect2, varscan2
- PDE4DIP | c.3945G>A p.E1315= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100519798; called by muse, mutect2, varscan2
- PDS5B | c.4104G>A p.Q1368= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1038851146, COSV100221072; called by muse, mutect2
- PIK3CG | c.453G>A p.Q151= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100782948; called by muse, mutect2, varscan2
- PIM3 | c.564C>A p.I188= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100638427, COSV62259502; called by muse, mutect2, varscan2
- PLCG1 | c.3312C>T p.G1104= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99718968; called by muse, mutect2, varscan2
- POLR3A | c.3786C>T p.A1262= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs184961157, COSV64931283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP1 | c.282G>A p.T94= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs373623359; called by muse, mutect2, varscan2
- POP1 | c.2076G>A p.R692= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100855911; called by muse, mutect2, varscan2
- PPIA | c.279G>A p.T93= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs1005967937, COSV100587831; called by muse, mutect2, varscan2
- PPM1K | c.759C>T p.H253= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs146016106; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R10 | c.1140G>A p.V380= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100919862; called by muse, mutect2, varscan2
- PREP | c.108A>G p.V36= (on ENST00000369110; = p.V102= on NM_002726.5) | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100964014; called by muse, mutect2, varscan2
- PRKCA | c.429C>T p.C143= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs149096693; called by muse, mutect2, varscan2
- PRKCG | c.1864C>T p.L622= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99669154; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1341G>A p.V447= (on ENST00000352766; = p.V368= on NM_181334.5) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100424361; called by muse, mutect2, varscan2
- PSTPIP1 | c.1044C>T p.I348= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs370740664, COSV99144048; called by muse, mutect2, varscan2
- PTPRD | c.1002C>T p.S334= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs149476744; called by muse, varscan2
- PTPRM | c.3255G>A p.P1085= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs200022785, COSV100157917; called by muse, mutect2, varscan2
- PZP | c.324G>A p.G108= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV54357479; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3600A>G p.L1200= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100741314; called by muse, mutect2, varscan2
- RAPGEF2 | c.3102T>C p.A1034= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs754966727, COSV100031285; called by muse, mutect2, varscan2
- RHCE | c.1036C>T p.L346= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs375909066; called by muse, mutect2, varscan2
- RHOBTB3 | c.1674T>C p.T558= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101183213; called by muse, mutect2, varscan2
- RMDN3 | c.585C>T p.D195= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs377576031; called by muse, mutect2, varscan2
- RNASE4 | c.150T>C p.D50= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs751045991, COSV100489382; called by muse, mutect2, varscan2
- RNF213 | c.15081C>T p.V5027= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs755452362, COSV60391515; called by muse, mutect2, varscan2
- RNF216 | c.1800C>T p.D600= (on ENST00000425013 / NM_207116.3; = p.D657= on NM_207111.4) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1299042343, COSV101111321; called by muse, mutect2
- SHROOM2 | c.3393C>A p.V1131= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV101098755; called by muse, mutect2, varscan2
- SIX3 | c.615C>T p.D205= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs1416827174, COSV53226354; called by muse, mutect2, varscan2
- SLC2A11 | c.924G>A p.A308= (on ENST00000345044 / NM_001024938.4; = p.A315= on NM_030807.5) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs763819996, COSV99741533; called by muse, mutect2, varscan2
- SLC30A2 | c.405C>T p.C135= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs958815166, COSV65332343; called by muse, mutect2, varscan2
- SLC38A1 | c.522C>A p.P174= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV101284224; called by muse, mutect2, varscan2
- SLC39A14 | c.117C>T p.S39= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs774725406, COSV99249830; called by muse, mutect2, varscan2
- SMG5 | c.2376C>T p.I792= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100700809, COSV100700907; called by muse, mutect2, varscan2
- SP4 | c.1734A>G p.V578= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV99754608; called by muse, mutect2, varscan2
- SPTAN1 | c.3822G>A p.K1274= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs1414198506, COSV100823673; called by muse, mutect2, varscan2
- SPTB | c.1614G>A p.L538= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV101072192; called by muse, mutect2, varscan2
- SRGAP2 | c.1947A>G p.S649= (on ENST00000624873 / NM_001170637.4; = p.S650= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV99832928; called by muse, mutect2, varscan2
- STAB1 | c.6549C>T p.R2183= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100195097; called by muse, mutect2, varscan2
- SULF2 | c.375C>T p.R125= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as COSV100737240; called by muse, mutect2, varscan2
- SULT1A2 | c.762C>T p.P254= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100187216; called by muse, mutect2, varscan2
- TCERG1 | c.939C>A p.A313= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV99694990; called by muse, mutect2, varscan2
- TDRD6 | c.5310C>T p.D1770= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100287776; called by muse, mutect2, varscan2
- TGM1 | c.1935T>C p.R645= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99253036; called by muse, mutect2, varscan2
- TICAM1 | c.939T>C p.S313= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99941138; called by muse, mutect2, varscan2
- TKT | c.1044G>A p.S348= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs200352787, COSV99965064; called by muse, mutect2, varscan2
- TLE4 | c.1236T>A p.A412= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV54639983, COSV99512352; called by muse, mutect2, varscan2
- TMC2 | c.2103G>T p.L701= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV100727668; called by muse, mutect2, varscan2
- TNS2 | c.4005C>T p.R1335= (on ENST00000314250 / NM_170754.4; = p.R1345= on NM_015319.2) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100036768; called by muse, mutect2, varscan2
- TTN | c.91956A>C p.T30652= (on ENST00000591111; = p.T23228= on NM_003319.4) | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs373707659, COSV100617608; called by muse, mutect2, varscan2
- TTN | c.14682C>T p.D4894= (on ENST00000591111; = p.D3967= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs534365478, COSV100600799; called by muse, mutect2, varscan2
- TXNRD2 | c.366G>T p.P122= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100538865, COSV57632349; called by muse, mutect2, varscan2
- UBQLN3 | c.174C>T p.P58= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs139187349; called by muse, mutect2, varscan2
- VGLL1 | c.180C>A p.P60= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV101034636; called by muse, mutect2, varscan2
- VNN2 | c.573T>C p.P191= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1299750091, COSV100426818; called by muse, mutect2
- VPS13D | c.11184C>T p.V3728= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs201339134, COSV99167107; called by muse, mutect2, varscan2
- WDR72 | c.15G>A p.L5= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100854605; called by muse, mutect2
- ZBED1 | c.333C>T p.A111= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs759623239, COSV100585644; called by muse, mutect2, varscan2
- ZBTB2 | c.309C>T p.H103= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs143199426; called by muse, mutect2, varscan2
- ZC3H10 | c.33C>T p.T11= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1312557796, COSV99230533; called by muse, mutect2, varscan2
- ZDHHC20 | c.975A>G p.K325= (on ENST00000400590 / NM_001330059.2; = p.K324= on NM_153251.3) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100203574; called by muse, mutect2
- ZFHX3 | c.24C>T p.V8= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs775146790, COSV99213289; called by muse, mutect2, varscan2
- ZNF317 | c.570C>T p.G190= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1421517266, COSV99927172; called by muse, mutect2, varscan2
- ZNF33B | c.354A>G p.Q118= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100847710; called by muse, mutect2, varscan2
- ACSL6 | c.993+96C>A | Intron (SNP) | VAF 17/29 reads (59%) | catalogued as COSV99733939; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852256 del A | 3'Flank (DEL) | VAF 19/37 reads (51%) | catalogued as rs770650493; called by mutect2, varscan2
- AP000769.5 | chr11:65500223 A>G | 5'Flank (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- ATP11A | c.*151A>G | 3'UTR (SNP) | VAF 18/51 reads (35%) | catalogued as rs756866181, COSV99368860; called by muse, mutect2, varscan2
- COPS9 | chr2:240126868 del C | 3'Flank (DEL) | VAF 10/34 reads (29%) | catalogued as COSV56228819; called by mutect2, pindel, varscan2
- FERMT1 | c.*698C>T | 3'UTR (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99451696; called by muse, mutect2, varscan2
- KRTAP8-1 | c.-2C>T | 5'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as rs751863794, COSV100297833; called by muse, mutect2
- MEST | c.181+632A>G | Intron (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99784323; called by muse, mutect2, varscan2
- MIR196A1 | n.69A>G | RNA (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- MIR487A | n.73del | RNA (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- MIR663B | n.11G>A | RNA (SNP) | VAF 8/50 reads (16%) | catalogued as rs747282419; called by muse, mutect2, varscan2
- PCDHA9 | c.2394+133T>C | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100969681; called by muse, mutect2, varscan2
- PRRX1 | c.599+3883T>C | Intron (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99509812; called by muse, mutect2
- RPL32 | c.-105G>C | 5'UTR (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99832776; called by muse, mutect2, varscan2
- SWI5 | c.-110G>A | 5'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100199682; called by muse, mutect2, varscan2
- ZAN | c.7787+54G>A | Intron (SNP) | VAF 15/48 reads (31%) | catalogued as rs374344638, COSV61804786; called by muse, mutect2, varscan2
